Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0V7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0V7-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: endometrium c54.1 h 51.11

The following statement may be applicable as part of the information used in completing the above report. This text was developed and its performance characteristics determined and tested and approved by the U.S. Food and Drug Administration. The FDA has determined that this statement or approval is not necessary. The text is used as general reference. A statement for approval is not required by law. This laboratory is located in the Clinical Laboratory Improvement Amendments of 1988 (CLIA) is qualified to perform high complexity clinical laboratory testing.

[page 2 of 3]
Surgical Pathology Report

- E. Left aortic node: No lymph nodes identified
- F. Right pelvic lymph nodes: Fifteen lymph nodes negative for metastasis (0/15)
- G. Right aortic node: One lymph node negative for metastasis (0/1)

Gross Description

- A. Received: In formalin is a single piece of previously opened soft tan tissue.
Labeled: "uterus, cervix"
Weight: 485 gms
Size: 13.8 x 12.6 x 6.9 cm
Appearance
Tumor
Location: Circumferential, body and fundus of uterus
Size: 9.4 x 5.5 x 2.7 cm
Appearance: Circumferential, granular, white, fungating, friable
Depth of invasion: Appears to involve at least the upper one half of the myometrium
Invasion of contiguous structures: None identified
Distance from margins: 3.6 cm from the cervical margin
Cervix: Smooth, shiny, white with no lesions identified
Endometrium: Uninvolved, endometrium is smooth, shiny, tan with areas of hemorrhage and mucoid material
Myometrium: 3.9 cm, with no areas of adenomyosis identified
Lymph nodes: None identified
Special studies: On request
Other findings: None

KEY TO CASSETTES:

- A1 - Cervix
A2 - Lower uterine segment
A3-A9 - Tumor and underlying myometrium
A10 - Right and left parametrium (right parametrium inked orange, left parametrium inked blue)

- B. Received in formalin labeled "R ovary" is a single segment of soft tan tissue, 11 gms, 6.2 x 3.7 x 1.4 cm. There is a fallopian tube, 5.1 x 0.6 x 0.5 cm, with multiple paratubal cystic structures, largest up to 1.7 x 1.4 x 1.4 cm, filled with clear serous fluid. There is an ovary, 2.4 x 2.0 x 1.0 cm, with a homogenous tan to white cut surface. There are multiple cystic structures, largest up to 1.1 x 1.0 x 1.0 cm, filled with clear serous fluid. Representative sections are submitted in two cassettes.
- C. Received in formalin labeled "L ovary" is a single segment of soft tan tissue, 16.0 gms, 6.3 x 4.1 x 2.5 cm. There is a fallopian tube, 5.1 x 0.6 x 0.5 cm, with multiple paratubal cystic structures, largest up to 1.6 x 1.0 x 0.8 cm. There is an ovary, 3.0 x 2.8 x 1.2 cm, with a previously opened cystic structure, 2.0 x 1.8 x 1.0 cm, partially filled with clotted blood. Representative sections are submitted in two cassettes.
- D. Received in formalin labeled "L pelvic LN" are multiple fragments of soft tan to yellow tissue, 23.0 gms, aggregating up to 6.0 x 4.8 x 3.0 cm. There are ten lymph nodes identified, largest up to 2.8 x 2.0 x 0.9 cm (inked blue). Submitted in toto in five cassettes, with largest lymph node in D1 (blue). One lymph node (red) in D2. Four lymph nodes in D3. Four lymph nodes in D4 and rest of specimen in D5.
- E. Received in formalin labeled "left aortic" are multiple fragments of soft tan to yellow tissue, <1.0 gm, aggregating up to 2.2 x 1.8 x 0.6 cm. One lymph node is identified, 0.4 x 0.3 x 0.3 cm (blue). Submitted in toto in one cassette.
- F. Received in formalin labeled "R pelvic LN" are multiple fragments of soft tan to yellow tissue, 20.0 gms, aggregating up to 6.5 x 4.8 x 2.2 cm. There are eight lymph nodes identified, largest up to 3.0 x 2.0 x 0.7 cm (blue). Submitted in toto in five cassettes, with largest lymph node in F1 (blue). Five lymph nodes in F2. Two lymph nodes in F3 and rest of specimen in F4 and F5.
- G. Received in formalin labeled "right aortic" are multiple pieces of soft tan to yellow tissue, 5.0 gm, aggregating up to 3.0 x 2.4 x 0.4 cm. There is one lymph node identified 3.3 x 2.1 x 0.5 cm (blue). Submitted in toto in one cassette.

[page 3 of 3]
[REDACTED]

Surgical Pathology Report

[REDACTED]

Microscopic Description

The microscopic findings support the above diagnosis.

***Electronically Signed Out By [REDACTED]

Source: NCI Genomic Data Commons file 2e45d289-6411-4fc4-8d5b-e64a714cc81e (TCGA-BS-A0V7.A4515806-9888-48E8-8F9E-491527FFC29C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).